Somatic mutation profile of tumor specimen TCGA-KQ-A41S-01A (aliquot TCGA-KQ-A41S-01A-12D-A339-08) from TCGA case TCGA-KQ-A41S, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 87.7 years (32,041 days).
Specimen TCGA-KQ-A41S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 582794bb-e832-4245-847c-6eb11507fbcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KQ-A41S-10C (Blood Derived Normal), aliquot TCGA-KQ-A41S-10C-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef9327c5-a088-476a-acd1-563179d77f9d

The open-access MAF lists 240 somatic variants for this specimen: 179 protein-altering or splice-affecting, 58 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 58, Nonsense Mutation 12, Splice Region 3, Splice Site 3, Frame Shift Del 3, Translation Start Site 1, Intron 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779517, CM000348, COSV58590095; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 14/340 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ABCD4 | c.1642G>C p.D548H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100084369; called by muse, mutect2
- ACIN1 | c.2184G>A p.G728= | Splice Region (SNP) | VAF 5/73 reads (7%) | catalogued as COSV99399853; called by muse, mutect2
- ACTR3B | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55448016; called by muse, mutect2, varscan2
- ADH1C | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV72463440; called by muse, mutect2, varscan2
- ADRA1D | c.1614G>C p.E538D | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV65240622; called by muse, mutect2, varscan2
- AKR7L | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV101334323; called by muse, mutect2, varscan2
- AMOT | c.1505G>A p.R502Q (on ENST00000371959 / NM_001113490.1; = p.R93Q on NM_133265.3) | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs776589824, COSV59062611; called by muse, mutect2, varscan2
- ANK1 | c.3682C>G p.L1228V | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1361453961, COSV55879306, COSV99052324, COSV99226757; called by muse, mutect2
- ANKRD30A | c.2003-1G>C p.X668_splice (on ENST00000611781; = p.X612_splice on NM_052997.2) | Splice Site (SNP) | VAF 24/88 reads (27%) | catalogued as COSV64608586; called by muse, mutect2, varscan2
- ANKS1A | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs1420259474, COSV64460083; called by muse, mutect2
- APPL1 | c.1022G>A p.C341Y | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758367000, COSV55700558; called by muse, mutect2, varscan2
- ATRX | c.2716G>A p.D906N | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV64875018; called by muse, mutect2, varscan2
- AXIN2 | c.473G>C p.R158T | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs748730853, COSV61057076, COSV61062017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAN | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV61255423; called by muse, mutect2
- BTBD11 | c.2308G>C p.E770Q (on ENST00000280758 / NM_001018072.2; = p.E307Q on NM_001017523.2) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55022441, COSV55024035; called by muse, mutect2, varscan2
- C12orf66 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.734); catalogued as COSV100320685, COSV61322944, COSV61324099; called by muse, mutect2, varscan2
- CACHD1 | c.2615C>T p.P872L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51551960; called by muse, mutect2, varscan2
- CACNB1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59998500; called by muse, mutect2
- CACNG7 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV55813999, COSV55817957; called by muse, mutect2, varscan2
- CC2D1A | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV58782628; called by muse, mutect2, varscan2
- CCDC190 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as COSV63362759; called by muse, mutect2, varscan2
- CDH1 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV55728434; called by muse, mutect2, varscan2
- CDH1 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99932239; called by muse, mutect2, varscan2
- CDH8 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV54861794; called by muse, mutect2, varscan2
- CELF2 | c.1037G>T p.G346V (on ENST00000416382 / NM_001025077.3; = p.G353V on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.613); catalogued as COSV59972659; called by muse, mutect2, varscan2
- CERS4 | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs752376928, COSV52166255; called by muse, mutect2, varscan2
- CFAP251 | c.2002T>G p.F668V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV56609691; called by muse, mutect2, varscan2
- CHD5 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52412604; called by muse, mutect2, varscan2
- CHST14 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.159); catalogued as rs886043666, COSV60378654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLPP | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.483); catalogued as COSV55536473; called by muse, mutect2, varscan2
- COL28A1 | c.3336C>G p.F1112L | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV68081720, COSV68083381; called by muse, mutect2
- CPN1 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100962653; called by muse, mutect2
- CSMD1 | c.9308C>T p.P3103L (on ENST00000520002; = p.P3102L on NM_033225.6) | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs984147998, COSV59277615; called by muse, mutect2
- CSMD2 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.382); catalogued as rs201989989; called by muse, mutect2, varscan2
- CSMD2 | c.1497G>C p.Q499H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV53903274; called by muse, mutect2
- CSMD3 | c.3763C>G p.P1255A (on ENST00000297405 / NM_001363185.1; = p.P1151A on NM_052900.3) | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52157333; called by muse, mutect2
- CTRL | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52123138; called by muse, mutect2, varscan2
- CUL3 | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV100023686, COSV100024408; called by muse, mutect2
- DIAPH2 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61261300, COSV61263823; called by muse, mutect2, varscan2
- DNAH7 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs780667721, COSV56760466; called by muse, mutect2, varscan2
- DNAJC11 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV53786035; called by muse, mutect2, varscan2
- DNAJC4 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV54173073; called by muse, mutect2, varscan2
- DOCK1 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99730780; called by muse, mutect2
- DPF2 | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52888961; called by muse, mutect2, varscan2
- DRP2 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV65810086; called by muse, mutect2, varscan2
- DYRK3 | c.1523C>G p.S508C | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV65605890; called by muse, mutect2, varscan2
- ECHDC1 | c.76C>G p.Q26E (on ENST00000531967 / NM_001139510.1; = p.Q20E on NM_018479.3) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as COSV58932247; called by muse, mutect2, varscan2
- EDNRB | c.536del p.P179Rfs*35 (on ENST00000377211 / NM_001201397.1; = p.P89Rfs*35 on NM_000115.5) | Frame Shift Del (DEL) | VAF 37/95 reads (39%) | catalogued as COSV57524395; called by mutect2, pindel, varscan2
- ELP5 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV59708505, COSV59708871; called by muse, mutect2
- EXPH5 | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV56201145; called by muse, mutect2, varscan2
- F8 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1296842178, CM980664, COSV64272224; called by muse, mutect2, varscan2
- FBXO16 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 38/155 reads (25%) | catalogued as rs776550852, COSV100672391; called by muse, mutect2, varscan2
- GALNT6 | c.1690G>C p.G564R | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62542007; called by muse, mutect2, varscan2
- GFRA3 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV51228379; called by muse, mutect2, varscan2
- GLUD2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV60151757; called by muse, mutect2, varscan2
- GOLGB1 | c.8119G>C p.E2707Q | Missense Mutation (SNP) | VAF 15/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61464770; called by muse, mutect2
- GPN1 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53114188; called by muse, mutect2, varscan2
- GPR143 | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV101102125; called by muse, mutect2
- HCN1 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.014); catalogued as rs776567935, COSV57499129; called by muse, mutect2, varscan2
- HJURP | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64978708; called by muse, mutect2, varscan2
- HOXA7 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs750774350, COSV54217337; called by muse, mutect2, varscan2
- IPO8 | c.2737C>G p.Q913E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.269); catalogued as rs751898645, COSV56240932; called by muse, mutect2, varscan2
- ITPRID2 | c.3526G>C p.E1176Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV57471015; called by muse, mutect2, varscan2
- KANSL3 | c.2458G>C p.G820R (on ENST00000666923 / NM_001349262.2; = p.G794R on NM_001115016.3) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV62616746; called by muse, mutect2, varscan2
- KAT2B | c.1353G>A p.M451I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55428542; called by muse, mutect2, varscan2
- KCNH5 | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59757795; called by muse, mutect2
- KCTD11 | c.746G>A p.R249Q (on ENST00000333751 / NM_001363642.1; = p.R210Q on NM_001002914.2) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.988); catalogued as rs1389456890, COSV50135136; called by muse, mutect2, varscan2
- KDF1 | c.774G>C p.E258D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV57671165; called by muse, mutect2, varscan2
- KDM5B | c.3971C>T p.S1324L | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV52509624; called by muse, mutect2
- KLHL2 | c.1607C>A p.A536E | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56976118; called by muse, mutect2, varscan2
- LCP2 | c.1562G>A p.R521K | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV50449038; called by muse, mutect2
- LRP1 | c.7457A>G p.N2486S | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1282253173, COSV54502184; called by muse, mutect2, varscan2
- MAP1LC3C | c.222G>C p.R74= | Splice Region (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100606493; called by muse, mutect2
- MAP3K7 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); catalogued as COSV65224165; called by muse, mutect2, varscan2
- MAT2A | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV52087934; called by muse, mutect2, varscan2
- MBOAT7 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs376939333; called by muse, mutect2, varscan2
- MCF2 | c.2497C>G p.Q833E | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV58482824; called by muse, mutect2, varscan2
- METTL3 | c.1543G>T p.D515Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52968419; called by muse, mutect2, varscan2
- METTL6 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV67542042; called by muse, mutect2, varscan2
- MOCS2 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63740669; called by muse, mutect2, varscan2
- MYLK | c.2290G>C p.D764H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV60608714; called by muse, mutect2
- MYT1 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1245535858, COSV60504237; called by muse, mutect2, varscan2
- NAV1 | c.1434G>C p.E478D | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.117); catalogued as COSV55216599; called by muse, mutect2
- NCOA7 | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57654503, COSV99996582; called by muse, mutect2, varscan2
- NEB | c.10696G>C p.E3566Q | Missense Mutation (SNP) | VAF 112/280 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV51117261; called by muse, mutect2, varscan2
- NEUROD4 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV54471257; called by muse, mutect2, varscan2
- NEUROD4 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54471265; called by muse, mutect2, varscan2
- NFIA | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV64536479, COSV64543864; called by muse, mutect2
- NSUN2 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 17/552 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV52953749; called by muse, mutect2
- OLAH | c.709C>G p.H237D (on ENST00000378228 / NM_001039702.3; = p.H290D on NM_018324.3) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62252436; called by muse, mutect2, varscan2
- OLFM2 | c.1125G>T p.M375I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as COSV53429780; called by muse, mutect2, varscan2
- OR9A2 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1455839265, COSV63306489; called by muse, mutect2, varscan2
- PACS1 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1179215624, COSV57697374; called by muse, mutect2, varscan2
- PAK3 | c.783G>A p.M261I (on ENST00000262836 / NM_001324328.2; = p.M246I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV53273315; called by muse, mutect2, varscan2
- PBRM1 | c.3856G>A p.D1286N (on ENST00000296302 / NM_001366071.2; = p.D1261N on NM_018313.5) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56271613; called by muse, mutect2, varscan2
- PCDH15 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.349); catalogued as COSV57294912; called by muse, mutect2, varscan2
- PCF11 | c.2923C>T p.Q975* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100018697, COSV53529288; called by muse, mutect2, varscan2
- PKHD1L1 | c.11728G>T p.E3910* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV101006471, COSV65754506; called by muse, mutect2, varscan2
- PNPLA7 | c.2417C>T p.T806M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs1485279836, COSV52997672; called by muse, mutect2, varscan2
- PPP2R2B | c.268G>C p.E90Q (on ENST00000394409; = p.E156Q on NM_181674.2) | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60758134, COSV60762604; called by muse, mutect2, varscan2
- PPP3CC | c.222G>C p.M74I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV51500611; called by muse, mutect2, varscan2
- PPT1 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV65655567; called by muse, mutect2, varscan2
- PRAMEF6 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 51/431 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs1213937863; called by muse, mutect2, varscan2
- PRKDC | c.9415C>T p.Q3139* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV100041291; called by muse, mutect2, varscan2
- PRKG2 | c.2224G>C p.D742H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52322959; called by muse, mutect2, varscan2
- PROS1 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as rs565325519, CM064171, COSV67775075; ClinVar: uncertain significance; called by muse, mutect2
- PSG2 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1058470, COSV61544511, COSV61545043; called by muse, mutect2, varscan2
- PTPRS | c.5198C>G p.S1733C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768527095, COSV53617177, COSV53637506; called by muse, mutect2, varscan2
- PUM1 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV57084227; called by muse, mutect2
- RAG1 | c.2335del p.V779* | Frame Shift Del (DEL) | VAF 26/63 reads (41%) | catalogued as CM081768, COSV55027798; called by mutect2, pindel, varscan2
- RASSF3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV51684908; called by muse, mutect2, varscan2
- RBM15 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV63923382; called by muse, mutect2, varscan2
- RCOR2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as rs371327834; called by muse, mutect2, varscan2
- REPS2 | c.1447C>G p.R483G | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58181199; called by muse, mutect2, varscan2
- RHOA | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV69042274; called by muse, mutect2, varscan2
- RORA | c.1117G>A p.D373N (on ENST00000335670 / NM_134261.3; = p.D398N on NM_002943.3) | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55038102; called by muse, mutect2, varscan2
- S1PR4 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV55739979, COSV99858924; called by muse, mutect2, varscan2
- SATB2 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99611637; called by muse, mutect2, varscan2
- SHOC1 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV59500089; called by muse, mutect2, varscan2
- SHROOM3 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs759875727, COSV56027584; called by muse, mutect2, varscan2
- SIN3B | c.3415G>C p.E1139Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV56132575, COSV99932057; called by muse, mutect2
- SLC16A10 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64354147; called by muse, mutect2
- SLC24A2 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as rs1370321620, COSV53862938; called by muse, mutect2, varscan2
- SLC27A2 | c.441C>G p.F147L | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV51058467, COSV51058665; called by muse, mutect2
- SMAD1 | c.1242G>C p.M414I | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as COSV57470944; called by muse, mutect2
- SMARCA4 | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV60791772; called by muse, mutect2
- SMC1A | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59128808, COSV59132023; called by muse, mutect2, varscan2
- SMG1 | c.9725C>T p.S3242F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.797); catalogued as COSV101246360; called by muse, mutect2, varscan2
- SMTNL1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV67699573; called by muse, mutect2, varscan2
- SOGA3 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64106248; called by muse, mutect2, varscan2
- SP140 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100613889; called by muse, mutect2, varscan2
- SPEF2 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV61547302; called by muse, mutect2
- TANC1 | c.4127G>C p.R1376T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55086576; called by muse, mutect2, varscan2
- TAS2R9 | c.792G>C p.L264F | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.678); catalogued as COSV53688195, COSV53688635; called by muse, mutect2, varscan2
- TAT | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63532661; called by muse, mutect2, varscan2
- TCF20 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV100166734; called by muse, mutect2, varscan2
- TENM2 | c.6361G>C p.E2121Q (on ENST00000518659 / NM_001122679.2; = p.E1882Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV69128039; called by muse, mutect2, varscan2
- TEPSIN | c.741G>C p.L247F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV56142446; called by muse, mutect2, varscan2
- TKFC | c.983-1G>A p.X328_splice | Splice Site (SNP) | VAF 23/138 reads (17%) | catalogued as COSV53651576, COSV53652588; called by muse, mutect2, varscan2
- TLN2 | c.6596A>G p.Q2199R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60888828; called by muse, mutect2, varscan2
- TLR9 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV62346432, COSV62347247; called by muse, mutect2
- TM7SF3 | c.590A>T p.Y197F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV58002070, COSV58003732; called by muse, mutect2, varscan2
- TMEM63B | c.2308-1G>C p.X770_splice | Splice Site (SNP) | VAF 8/71 reads (11%) | catalogued as COSV52478207, COSV99440807; called by muse, mutect2, varscan2
- TMIGD1 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV61028423; called by muse, mutect2
- TOP3B | c.1893G>A p.M631I | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV64116990; called by muse, mutect2, varscan2
- TP53BP1 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55499644; called by muse, mutect2, varscan2
- TPT1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); catalogued as COSV58538617; called by muse, mutect2, varscan2
- TRAF4 | c.141C>G p.L47= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as COSV52044416; called by muse, mutect2
- TRPS1 | c.2353T>A p.S785T (on ENST00000220888 / NM_001330599.2; = p.S798T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/442 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV55236276; called by muse, mutect2, varscan2
- TTC13 | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs916813120, COSV64168379; called by muse, mutect2
- TTC39A | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV52957608, COSV99397107; called by muse, mutect2, varscan2
- TTN | c.85793C>T p.A28598V (on ENST00000591111; = p.A21174V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | PolyPhen probably damaging (0.997); catalogued as COSV59997355; called by muse, mutect2, varscan2
- TUT7 | c.4168G>A p.E1390K | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV52895216, COSV52897484; called by muse, mutect2, varscan2
- TXNIP | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782719383, COSV65220282; called by muse, mutect2
- UBE3C | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as rs917285919, COSV61952623; called by muse, mutect2
- USP35 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.949); catalogued as rs1482135718, COSV71572715; called by muse, mutect2
- USP48 | c.1576A>G p.I526V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs200891466; called by muse, mutect2, varscan2
- UTP20 | c.8119G>C p.E2707Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55375574; called by muse, mutect2, varscan2
- WAPL | c.3064G>A p.D1022N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53934328; called by muse, mutect2, varscan2
- ZC3H13 | c.4580T>G p.M1527R (on ENST00000242848 / NM_001330565.2; = p.M1528R on NM_015070.6) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV54451909; called by muse, mutect2, varscan2
- ZIM2 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as COSV55630925; called by muse, mutect2, varscan2
- ZMYM4 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV58909387; called by muse, mutect2
- ZNF16 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 37/63 reads (59%) | catalogued as COSV99429717; called by muse, mutect2, varscan2
- ZNF160 | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); catalogued as COSV61999459; called by muse, mutect2
- ZNF215 | c.171G>C p.L57F | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV53492612, COSV53493684; called by muse, mutect2, varscan2
- ZNF337 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs779513514, COSV53321063; called by muse, mutect2, varscan2
- ZNF468 | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); catalogued as COSV54694363; called by muse, mutect2, varscan2
- ZNF480 | c.848G>C p.R283T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs780898066, COSV57995755; called by muse, mutect2, varscan2
- ZNF699 | c.797T>G p.F266C | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV58025362; called by muse, mutect2
- ZNF749 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV61945836; called by muse, mutect2, varscan2
- ZNF804A | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56463569; called by muse, mutect2
- ZSCAN20 | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV63682360; called by muse, mutect2, varscan2
- PRKCH | c.1151_1166del p.K384Tfs*2 | Frame Shift Del (DEL) | VAF 47/129 reads (36%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYTL5 | c.1242C>G p.I414M | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ABCG5 | c.1830G>A p.E610= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV53183139; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1071G>A p.L357= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV68343905, COSV68344516; called by muse, mutect2, varscan2
- ADAM23 | c.474C>T p.F158= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs141683172; ClinVar: likely benign; called by mutect2, varscan2
- ADCY2 | c.2406G>A p.L802= | Silent (SNP) | VAF 19/211 reads (9%) | catalogued as COSV57868724; called by muse, mutect2
- AGO2 | c.909G>A p.T303= | Silent (SNP) | VAF 65/146 reads (45%) | catalogued as rs1160560384, COSV55046743; called by muse, mutect2, varscan2
- AHNAK | c.12204C>T p.F4068= | Silent (SNP) | VAF 38/282 reads (13%) | catalogued as rs1281396440, COSV57211118; called by muse, mutect2, varscan2
- AIF1 | c.366G>C p.L122= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV61962343; called by muse, mutect2
- ANXA9 | c.960C>T p.L320= | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as COSV56498431; called by muse, mutect2, varscan2
- AOPEP | c.414G>C p.G138= | Silent (SNP) | VAF 11/246 reads (4%) | catalogued as COSV52917044; called by muse, mutect2
- APC2 | c.459C>G p.L153= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1253795727, COSV99279615; called by muse, mutect2
- ARHGAP4 | c.429C>T p.V143= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV63131697; called by muse, mutect2, varscan2
- BNC2 | c.2757G>A p.K919= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV66163716; called by muse, mutect2, varscan2
- BRF1 | c.381G>A p.K127= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV59268019; called by muse, mutect2
- C9 | c.1347G>A p.V449= | Silent (SNP) | VAF 14/149 reads (9%) | catalogued as COSV54676184; called by muse, mutect2
- CACNA1E | c.4749C>T p.L1583= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV62390574; called by muse, mutect2, varscan2
- CHD7 | c.7722T>G p.L2574= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV71109340; called by muse, mutect2
- CUBN | c.7287G>A p.R2429= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV64713828; called by muse, mutect2, varscan2
- CYP4F3 | c.684C>T p.L228= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as rs1291121288, COSV55409085, COSV55410586; called by muse, mutect2, varscan2
- DOCK2 | c.147C>G p.L49= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as COSV56953877; called by muse, mutect2, varscan2
- ELAPOR2 | c.3012C>T p.L1004= (on ENST00000450689 / NM_001142749.3; = p.L837= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as COSV51885930; called by muse, mutect2
- EXOC6B | c.814C>T p.L272= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV55547109; called by muse, mutect2, varscan2
- F12 | c.969G>C p.P323= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1371742536, COSV53691021, COSV53692767; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1662C>T p.I554= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV100441186; called by muse, varscan2
- GTF2IRD2B | c.1824C>T p.I608= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV57030858; called by muse, mutect2, varscan2
- IBTK | c.2925C>T p.F975= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV60392310; called by muse, mutect2, varscan2
- ITPRIPL1 | c.96G>A p.R32= (on ENST00000439118 / NM_001008949.3; = p.R40= on NM_178495.6) | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV63153085; called by muse, varscan2
- KBTBD6 | c.174T>C p.D58= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs774398240, COSV65271507; called by muse, mutect2, varscan2
- KIAA0319 | c.24C>T p.L8= | Silent (SNP) | VAF 15/167 reads (9%) | catalogued as rs754397234, COSV65496159; called by muse, mutect2
- KRT73 | c.630C>T p.S210= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs116369374, COSV59838771; called by muse, mutect2, varscan2
- KY | c.1131G>A p.P377= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs753136567, COSV71017060; ClinVar: likely benign; called by muse, mutect2, varscan2
- LHX2 | c.255C>T p.L85= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV101010069, COSV65318229; called by mutect2, varscan2
- LIPA | c.249C>T p.F83= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV51078641; called by muse, mutect2, varscan2
- MAGI2 | c.3996C>G p.P1332= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs770918988, COSV100835192; called by muse, varscan2
- MED24 | c.1846C>T p.L616= | Silent (SNP) | VAF 26/268 reads (10%) | catalogued as COSV62418185; called by muse, mutect2
- MLH1 | c.57C>T p.I19= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs762647509, COSV51616921, COSV51623813; called by muse, mutect2, varscan2
- NBEAL2 | c.1686C>T p.I562= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs928231294, COSV52756648; called by muse, mutect2, varscan2
- NUP210L | c.1563G>A p.G521= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV55146017; called by muse, mutect2
- OR4D9 | c.906G>A p.K302= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV61434485; called by muse, mutect2, varscan2
- OR5D14 | c.216T>C p.D72= | Silent (SNP) | VAF 45/75 reads (60%) | catalogued as rs1357880625, COSV59456047; called by muse, mutect2, varscan2
- PLA2G5 | c.123C>T p.Y41= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs369115056; called by muse, mutect2, varscan2
- RAPGEF3 | c.2589C>T p.L863= (on ENST00000389212; = p.L821= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV50201965, COSV99406705; called by muse, mutect2, varscan2
- RELN | c.6117G>C p.V2039= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV58996086, COSV58997145; called by muse, mutect2, varscan2
- RIMBP3 | c.1236G>A p.E412= | Silent (SNP) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- RPA4 | c.603C>T p.I201= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs1374457614, COSV61266387; called by muse, mutect2, varscan2
- RPL11 | c.171A>G p.R57= (on ENST00000374550 / NM_001199802.1; = p.R58= on NM_000975.5) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs752965630, COSV65778597; called by muse, mutect2, varscan2
- RYR2 | c.14670C>T p.I4890= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs746256286, COSV63679811; called by muse, mutect2, varscan2
- SCYL3 | c.937C>T p.L313= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as rs1211315309, COSV63045620; called by muse, mutect2, varscan2
- SHLD2 | c.2052G>A p.L684= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV53954270; called by muse, mutect2
- SIM1 | c.705C>T p.R235= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV53491026; called by muse, mutect2, varscan2
- SLC16A1 | c.1416G>T p.G472= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV63709120; called by muse, mutect2, varscan2
- SLC7A3 | c.1842C>G p.L614= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV53227167; called by muse, mutect2, varscan2
- TFRC | c.1821G>A p.L607= | Silent (SNP) | VAF 50/261 reads (19%) | catalogued as COSV64054507; called by muse, mutect2, varscan2
- TMC7 | c.1722C>A p.I574= | Silent (SNP) | VAF 38/278 reads (14%) | catalogued as COSV58582924, COSV58587723; called by muse, mutect2, varscan2
- VEGFC | c.1128C>T p.F376= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as COSV54596848; called by muse, mutect2
- XPR1 | c.1215G>A p.V405= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV62554774, COSV62555901; called by muse, mutect2, varscan2
- ZC3H7A | c.1683C>T p.L561= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs1458978778, COSV63269247, COSV63269263; called by muse, mutect2, varscan2
- ZNF362 | c.435G>T p.P145= | Silent (SNP) | VAF 80/232 reads (34%) | catalogued as COSV65031349; called by muse, mutect2, varscan2
- ZNF616 | c.1590C>T p.F530= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs1377012322, COSV57510539; called by muse, mutect2, varscan2
- ATAD2 | c.1897+100G>A | Intron (SNP) | VAF 15/40 reads (38%) | catalogued as rs1039680238, COSV99784912; called by muse, mutect2, varscan2
- PWWP3A | chr19:1376575 G>C | 3'Flank (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100262142; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 5/28 reads (18%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2
